Somatic mutation profile of tumor specimen C3L-00765-01 (aliquot CPT0015910006) from CPTAC case C3L-00765, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 61.2 years (22,351 days).
Specimen C3L-00765-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa8d21f5-f817-46b4-8303-2cb326f9c453.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00765-31 (Blood Derived Normal), aliquot CPT0018310001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4facf85-662c-4853-8124-19813ced45bb

The open-access MAF lists 55 somatic variants for this specimen: 41 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 8, Nonsense Mutation 3, Frame Shift Del 3, RNA 2, Splice Site 2, Intron 1, 5'UTR 1, 5'Flank 1, Splice Region 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAHCC1 | c.5849G>A p.R1950Q | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782751405, COSV57033926; called by muse, mutect2, varscan2
- BRD2 | c.827A>G p.K276R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.313); catalogued as rs774228931; called by muse, varscan2
- CDC37 | c.796C>A p.R266S | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as COSV55768508; called by muse, mutect2, varscan2
- EPHA1 | c.2852+1G>C p.X951_splice | Splice Site (SNP) | VAF 68/321 reads (21%) | catalogued as COSV51969088; called by muse, mutect2, varscan2
- FDPS | c.1075A>G p.K359E | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1378366565; called by muse, mutect2, varscan2
- HSD17B14 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.017); catalogued as rs760796044, COSV54414915; called by muse, varscan2
- MYL6B | c.*9+7C>T | Splice Region (SNP) | VAF 39/210 reads (19%) | catalogued as rs977232370; called by muse, mutect2, varscan2
- NAV3 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs375778220, COSV57077197; called by muse, mutect2, varscan2
- SLC37A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/372 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1239265740; called by muse, mutect2
- ZNF296 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV54320190; called by muse, mutect2
- ABCC4 | c.968C>A p.S323* | Nonsense Mutation (SNP) | VAF 47/380 reads (12%) | called by muse, mutect2, varscan2
- ADNP | c.567T>G p.F189L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ALDH1A1 | c.1206del p.F402Lfs*8 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- ANHX | c.377+1G>T p.X126_splice | Splice Site (SNP) | VAF 18/291 reads (6%) | called by muse, mutect2
- CDCA7 | c.286G>A p.E96K (on ENST00000347703 / NM_145810.3; = p.E175K on NM_031942.5) | Missense Mutation (SNP) | VAF 57/440 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, varscan2
- DMRTA1 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- DNAH17 | c.11975del p.N3992Tfs*173 | Frame Shift Del (DEL) | VAF 24/157 reads (15%) | called by mutect2, pindel, varscan2
- DTX1 | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- EPHB3 | c.1272G>C p.E424D | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GFM2 | c.1751A>G p.D584G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GOT1 | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HSPG2 | c.4075G>A p.V1359M | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2
- KDM3A | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- MAP3K20 | c.2242_2243delinsA p.L748Sfs*84 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | called by pindel, varscan2*
- MYO5B | c.4889T>A p.L1630Q | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- NAXE | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- PADI6 | c.803A>T p.E268V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2
- PCK2 | c.1466A>G p.K489R | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PLEKHM3 | c.1889T>A p.I630N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PTCH2 | c.2665A>C p.K889Q | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- PTPRZ1 | c.4942A>C p.T1648P | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RBM38 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SCYL1 | c.1859C>T p.T620I | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2
- SLC25A44 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SLCO4A1 | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- SMG1 | c.2189T>A p.L730Q | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- WDR33 | c.1017G>A p.W339* | Nonsense Mutation (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.566T>A p.L189H | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ZNF341 | c.288_299del p.S97_P100del | In Frame Del (DEL) | VAF 34/264 reads (13%) | called by mutect2, pindel
- ZNF532 | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZNF81 | c.1619A>C p.N540T | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- BMX | c.669C>A p.I223= | Silent (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- GAPDH | c.345A>G p.G115= | Silent (SNP) | VAF 54/287 reads (19%) | catalogued as rs753299793; called by muse, mutect2, varscan2
- KCNH5 | c.771T>A p.I257= | Silent (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- MYO5B | c.4890A>T p.L1630= | Silent (SNP) | VAF 34/239 reads (14%) | called by muse, mutect2, varscan2
- PRPF19 | c.1497C>A p.L499= | Silent (SNP) | VAF 38/215 reads (18%) | called by muse, mutect2, varscan2
- RAB3GAP2 | c.3942T>C p.H1314= | Silent (SNP) | VAF 31/271 reads (11%) | catalogued as rs146611810; called by muse, mutect2, varscan2
- RBM10 | c.2661T>C p.P887= | Silent (SNP) | VAF 62/583 reads (11%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.1155A>G p.G385= | Silent (SNP) | VAF 30/127 reads (24%) | called by muse, mutect2, varscan2
- AC104825.1 | n.1445T>C | RNA (SNP) | VAF 31/248 reads (13%) | called by muse, mutect2, varscan2
- ASS1 | c.-1T>C | 5'UTR (SNP) | VAF 85/804 reads (11%) | called by muse, mutect2, varscan2
- MFSD8 | c.1102+35dup | Intron (INS) | VAF 24/185 reads (13%) | called by mutect2, pindel, varscan2
- MPV17L2 | c.*325A>G | 3'UTR (SNP) | VAF 81/527 reads (15%) | catalogued as rs1227968381; called by muse, mutect2, varscan2
- NUP98 | chr11:3797990 T>G | 5'Flank (SNP) | VAF 17/364 reads (5%) | catalogued as rs1434356357; called by muse, mutect2
- TXNRD3 | n.665G>A | RNA (SNP) | VAF 20/98 reads (20%) | catalogued as rs748697446; called by muse, mutect2, varscan2
